Surgical pathology report (de-identified scan), TCGA case TCGA-3M-AB46, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Kansas Medical Center, specimen TCGA-3M-AB46-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

NAME:

MR #:

BILLING #:

LOCATION:

AGE:

SEX: M

DOB:

PHYSICIAN:

COPY TO:

SURG PATH #:

SPECIMEN CLASS:

ALT ID #:

DATE OF PROCEDURE:

DATE RECEIVED:

TIME RECEIVED:

DATE OF REPORT:

DATE OF PRINTING:

Material Received:

A: liver lesion history of gastric cancer

B: subtotal gastrectomy

History:

-year-old male with a clinical history of gastric cancer.

Final Diagnosis:

A. Liver, "liver lesion", biopsy:

Benign calcified hyaline nodules (x 2).

B. Stomach and lymph nodes (12), subtotal gastrectomy:

Stomach: Moderately differentiated adenocarcinoma (see checklist).

Intestinal metaplasia and marked chronic inflammation.

Lymph nodes (15): There is no evidence of malignancy in fifteen lymph nodes (0/15).

Comment:

Stomach Cancer Checklist

Specimen Type: Sub-total gastrectomy

Tumor Site: Lesser curvature

Tumor Configuration: Exophytic

Tumor Size: 3.0 x 3.0 x 1.0 cm

Surgical Margins:

Proximal Margin: 0.6 cm

Distal Margin: 13.0 cm

Circumferential (Radial) Margin: Invasive tumor invades through the muscularis propria into the subserosa and is < 0.1 cm from the inked circumferential margin, however the tumor does not penetrate the serosa.

Histologic Type: Adenocarcinoma

Histologic Grade: Moderately differentiated

Lymphatic (Small Vessel) Invasion: Present

Venous (Large Vessel) Invasion: Absent

Perineural Invasion: Present

Lymph Nodes:

Number Examined: 15

Number Involved: 0

Prognostic Markers: Ordered. See for addendum Image Analysis report

Additional Pathologic Findings: Intestinal metaplasia

Gross Picture Taken: No

MR #:

Page 1 of 2

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Pathologic Staging: pT2b N0 MX
pT2b: Tumor invades subserosa
pN0: No regional lymph node metastasis
pMX: Cannot be assessed

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh labeled with the patient's name and "liver lesion" is one fragment of tan-brown soft tissue measuring 0.5 x 0.4 x 0.4 cm. The specimen is submitted for frozen section in cassette A1FS.

B. Received fresh labeled with the patient's name and "subtotal gastrectomy" is a portion of stomach measuring 17.0 cm along the greater curvature, 11.0 cm along the lesser curvature, and 10.0 cm in diameter. The serosal surface is tan-brown, smooth and glistening with a focal area of induration measuring 0.5 x 0.5 cm. The stomach is opened along the greater curvature to reveal a 3.0 x 3.0 x 1.0 cm exophytic mass with raised borders. The mass is located 0.6 cm from the proximal margin and 13.0 cm from the distal margin. Grossly the tumor does not extend through the serosa. The rugal folds are grossly unremarkable and the thickness of the gastric wall ranges from 0.3 cm to 0.5 cm. The attached omentum measures 30.0 x 20.0 x 5.0 cm. It is serially sectioned to examine for lymph nodes. The specimen is submitted as follows:

B3-B12 - Entire mass
B13 - Distal resection margin
B14 - Representative sections of normal appearing stomach
B15-B23 - Possible lymph nodes
B24- Three possible lymph nodes, all bisected
B25- Three possible lymph nodes two bisected.
B26- One lymph node

Intraoperative Consultation:

A1FS, liver, "liver lesion":

Benign calcified nodule (x 2).

B1FS, stomach, "subtotal gastrectomy", margin:

Negative for carcinoma.
Intestinal metaplasia and reactive changes.

B2FS, stomach, "subtotal gastrectomy", margin:

Representative section of tumor, adenocarcinoma.
Tumor is submitted for

If immunohistochemical stains and/or in situ hybridization are cited in this report, the performance characteristics were determined by the regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA. Known positive and negative control tissues demonstrate appropriate staining. This testing was developed by the It has not been cleared or approved by the FDA. The FDA has determined that such clearance or approval is not necessary.

Date of Printing:

MR #:

SURGICAL PATHOLOGY

Source: NCI Genomic Data Commons file a6ab4eed-ea5a-4421-a852-4929b7159425 (TCGA-3M-AB46.3A3C6F93-253B-44E5-94E4-2FA31ED689AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).